Somatic mutation profile of tumor specimen C3N-03782-01 (aliquot CPT0245630006) from CPTAC case C3N-03782, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 50.8 years (18,540 days).
Specimen C3N-03782-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c02dfd77-f514-4c5c-ad9c-04518bd2cd79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03782-31 (Blood Derived Normal), aliquot CPT0245670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ce366dc-b11e-4e91-83c9-b03c2646c103

The open-access MAF lists 114 somatic variants for this specimen: 77 protein-altering or splice-affecting, 21 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 21, Intron 7, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 3, 5'Flank 3, RNA 2, 5'UTR 2, 3'Flank 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 292/426 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ALPK3 | c.2398C>A p.L800I | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.073); catalogued as rs141673424; called by muse, mutect2, varscan2
- ARMC4 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs376424270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHEK2 | c.539G>A p.R180Q (on ENST00000382580 / NM_001005735.2; = p.R137Q on NM_007194.4) | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as rs368570187, CM023899, COSV60423503; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CILP2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs770509171; called by muse, mutect2, varscan2
- COL6A3 | c.8555G>A p.G2852D | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55090634; called by muse, mutect2, varscan2
- CYYR1 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as rs748380673, COSV54835572, COSV54835900; called by muse, mutect2, varscan2
- FLG2 | c.2392G>A p.G798R | Missense Mutation (SNP) | VAF 164/400 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs879140814, COSV101166262; called by muse, mutect2, varscan2
- KCNA1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 50/718 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838319; called by muse, mutect2
- MOV10 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.179); catalogued as rs775468592, COSV62491839; called by muse, varscan2
- MSR1 | c.658T>A p.Y220N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs781409313; called by muse, mutect2, varscan2
- MYCN | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 98/183 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1412185126; called by muse, mutect2, varscan2
- NBEA | c.4882G>A p.A1628T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.956); catalogued as COSV59834637; called by muse, mutect2, varscan2
- PHF8 | c.2669C>T p.P890L (on ENST00000357988 / NM_001184896.1; = p.P854L on NM_015107.3) | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs781843717, COSV100153915; called by muse, mutect2, varscan2
- PKD1 | c.11098C>T p.R3700C (on ENST00000262304 / NM_001009944.3; = p.R3699C on NM_000296.4) | Missense Mutation (SNP) | VAF 288/398 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs758831274; called by muse, mutect2, varscan2
- PLXNB3 | c.3742T>C p.S1248P | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs782152760; called by muse, mutect2
- PRAMEF11 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779781284; called by muse, mutect2, varscan2
- PRLHR | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs749626114, COSV99492601; called by muse, mutect2, varscan2
- PROM1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs369512467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPF1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763959246, COSV65705732; called by muse, mutect2, varscan2
- SBF1 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 44/128 reads (34%) | catalogued as rs1556436485; called by muse, mutect2, varscan2
- SCN4A | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1398605254, COSV101438278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC1B | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs1323135739; called by muse, mutect2, varscan2
- STS | c.1060G>T p.G354* | Nonsense Mutation (SNP) | VAF 72/182 reads (40%) | catalogued as CM159957, COSV54268729; called by muse, mutect2, varscan2
- TECTA | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs192787819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRMT10B | c.186G>A p.S62= | Splice Region (SNP) | VAF 14/49 reads (29%) | catalogued as rs373829295; called by muse, varscan2
- TYK2 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs755089851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFHX2 | c.5915C>T p.T1972M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.513); catalogued as rs780187038; called by muse, mutect2, varscan2
- ZNF99 | c.2557C>A p.L853I | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs747884760; called by muse, mutect2, varscan2
- ABCB4 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 85/648 reads (13%) | called by muse, mutect2, varscan2
- AGAP9 | c.1688A>G p.K563R | Missense Mutation (SNP) | VAF 180/858 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- API5 | c.1532dup p.W512Lfs*8 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel
- ATG9A | c.1266-1G>T p.X422_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- CAPN11 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CASTOR2 | c.830-1G>T p.X277_splice | Splice Site (SNP) | VAF 312/793 reads (39%) | called by muse, mutect2, varscan2
- CCDC93 | c.983A>C p.Q328P | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); called by muse, mutect2
- CD40LG | c.106A>G p.M36V | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CDH8 | c.538T>A p.S180T | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2
- CFAP97 | c.1596A>T p.L532F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CHML | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CMYA5 | c.10042G>A p.V3348I | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- COL7A1 | c.4238C>T p.P1413L | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPD | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 147/390 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CRY1 | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DTX3L | c.492_493del p.K164Nfs*8 | Frame Shift Del (DEL) | VAF 44/185 reads (24%) | called by mutect2, pindel, varscan2
- ERCC3 | c.1720del p.R574Dfs*2 | Frame Shift Del (DEL) | VAF 31/325 reads (10%) | called by mutect2, pindel, varscan2
- FRY | c.3153T>A p.N1051K | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- GRIK5 | c.1457G>C p.G486A | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GSAP | c.534A>C p.E178D | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- IQCG | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 200/588 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LIN7A | c.50T>C p.L17S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP1B | c.12612T>A p.N4204K | Missense Mutation (SNP) | VAF 104/206 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRP1B | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEA10 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2
- MOV10L1 | c.3518G>A p.G1173E | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A4A | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEB | c.15750C>G p.I5250M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- NFKBID | c.7-1G>C p.X3_splice (on ENST00000396901; = p.X155_splice on NM_032721.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- NSD1 | c.5362A>T p.R1788* | Nonsense Mutation (SNP) | VAF 167/292 reads (57%) | called by muse, mutect2, varscan2
- OR4A16 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.251); called by muse, mutect2
- OR6C3 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PCDHA1 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PKHD1L1 | c.10004C>A p.S3335Y | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PRAMEF10 | c.338G>T p.W113L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by mutect2, varscan2
- PRMT2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF17 | c.118T>A p.S40T | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN4A | c.4125C>A p.D1375E | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SERPINE2 | c.453T>G p.D151E | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, varscan2
- SLITRK2 | c.583del p.V195* | Frame Shift Del (DEL) | VAF 145/328 reads (44%) | called by mutect2, pindel, varscan2
- SOBP | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 75/532 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TAF1 | c.3371A>G p.N1124S (on ENST00000373790 / NM_138923.4; = p.N1145S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF15 | c.1250G>T p.G417V (on ENST00000605844 / NM_139215.3; = p.G414V on NM_003487.4) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TMEM63B | c.1968C>G p.H656Q | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDR54 | c.614T>A p.L205* | Nonsense Mutation (SNP) | VAF 42/292 reads (14%) | called by muse, varscan2
- YARS1 | c.839A>T p.D280V | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YARS2 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 81/653 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF138 | c.541C>G p.R181G (on ENST00000307355 / NM_001367572.1; = p.R155G on NM_006524.4) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ACAP1 | c.504A>T p.G168= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- ASXL3 | c.360T>C p.C120= | Silent (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- CA14 | c.555G>A p.R185= | Silent (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- CHD9 | c.312A>C p.P104= | Silent (SNP) | VAF 104/229 reads (45%) | called by muse, mutect2, varscan2
- CPA4 | c.105C>T p.D35= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs377703859; called by muse, mutect2, varscan2
- FAM117B | c.1260C>T p.T420= | Silent (SNP) | VAF 58/258 reads (22%) | catalogued as rs775978887; called by muse, mutect2, varscan2
- FLI1 | c.804G>A p.P268= | Silent (SNP) | VAF 45/310 reads (15%) | catalogued as rs1363259180, COSV55642670; called by muse, mutect2, varscan2
- INTS8 | c.1770A>G p.K590= | Silent (SNP) | VAF 127/237 reads (54%) | catalogued as rs777957478; called by muse, mutect2, varscan2
- KALRN | c.2883G>A p.Q961= | Silent (SNP) | VAF 153/459 reads (33%) | called by muse, mutect2, varscan2
- KIAA1210 | c.2349A>C p.S783= | Silent (SNP) | VAF 33/165 reads (20%) | called by muse, mutect2, varscan2
- LIPH | c.252T>A p.P84= | Silent (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- LRRC70 | c.288T>A p.I96= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- MYH2 | c.249C>A p.P83= | Silent (SNP) | VAF 88/537 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.1584C>T p.S528= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs754795176, COSV52776332; called by muse, varscan2
- PSMA2 | c.9G>A p.E3= | Silent (SNP) | VAF 87/240 reads (36%) | catalogued as rs763261249, COSV56238149; called by muse, mutect2, varscan2
- SPEF2 | c.5301G>A p.E1767= | Silent (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- SPOCD1 | c.300C>T p.L100= | Silent (SNP) | VAF 56/282 reads (20%) | called by muse, mutect2, varscan2
- TAF1L | c.3927G>A p.S1309= | Silent (SNP) | VAF 47/335 reads (14%) | catalogued as rs776454125, COSV54260539; called by muse, mutect2, varscan2
- TUBGCP3 | c.1845T>C p.P615= | Silent (SNP) | VAF 76/237 reads (32%) | called by muse, mutect2, varscan2
- WDR54 | c.615G>A p.L205= | Silent (SNP) | VAF 40/286 reads (14%) | called by muse, varscan2
- ZNF711 | c.234A>C p.T78= | Silent (SNP) | VAF 33/192 reads (17%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4744C>T | Intron (SNP) | VAF 60/272 reads (22%) | called by muse, mutect2, varscan2
- BAIAP2 | chr17:81032918 C>T | 5'Flank (SNP) | VAF 56/136 reads (41%) | catalogued as rs754398551; called by muse, varscan2
- BUB1B | c.1402-15A>G | Intron (SNP) | VAF 57/180 reads (32%) | called by muse, mutect2, varscan2
- CACNB3 | chr12:48814453 T>C | 5'Flank (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- CCT3 | c.304+299C>T | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as rs1440084044; called by muse, mutect2, varscan2
- CICP28 | chr7:56812237 C>T | 3'Flank (SNP) | VAF 21/297 reads (7%) | catalogued as rs782192215; called by muse, mutect2
- CLEC19A | chr16:19309036 C>T | 3'Flank (SNP) | VAF 91/129 reads (71%) | catalogued as rs899387498; called by muse, mutect2, varscan2
- HBB | c.93-10C>A | Intron (SNP) | VAF 154/446 reads (35%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2231+22366C>A | Intron (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- LINC02381 | n.254C>G | RNA (SNP) | VAF 78/147 reads (53%) | called by muse, mutect2, varscan2
- LRCH1 | c.1527+113C>G | Intron (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- MIR200B | n.58A>C | RNA (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- NIBAN1 | c.-74C>A | 5'UTR (SNP) | VAF 43/247 reads (17%) | called by muse, mutect2, varscan2
- TFPI | c.535+20C>A | Intron (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- TTI2 | chr8:33513505 G>C | 5'Flank (SNP) | VAF 30/119 reads (25%) | catalogued as rs767938561; called by muse, mutect2, varscan2
- XIRP2 | c.-36T>A | 5'UTR (SNP) | VAF 57/117 reads (49%) | catalogued as COSV54735213; called by muse, mutect2, varscan2
